Somatic mutation profile of tumor specimen TCGA-FB-AAQ6-01A (aliquot TCGA-FB-AAQ6-01A-11D-A40W-08) from TCGA case TCGA-FB-AAQ6, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Tail of pancreas; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 85.7 years (31,319 days).
Specimen TCGA-FB-AAQ6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c93d8b40-9619-4f2b-85bc-9529f6cf78e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FB-AAQ6-11A (Solid Tissue Normal), aliquot TCGA-FB-AAQ6-11A-11D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b539844-278d-4f16-9b5b-fb3340435382

The open-access MAF lists 65 somatic variants for this specimen: 48 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 15, Nonsense Mutation 5, Frame Shift Ins 2, Frame Shift Del 1, Intron 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 57/248 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1054G>T p.G352* | Nonsense Mutation (SNP) | VAF 115/309 reads (37%) | hotspot (GDC flag); catalogued as CM024126, COSV61684989, COSV61690191; called by muse, mutect2, varscan2
- SMAD4 | c.1055G>T p.G352V | Missense Mutation (SNP) | VAF 115/308 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM100518, COSV61684254, COSV61684836, COSV61691577; called by muse, mutect2, varscan2
- TGFBR2 | c.1609C>T p.R537C | Missense Mutation (SNP) | VAF 129/276 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104893809, CM042122, CM064325, COSV55442890; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 38/184 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AIFM1 | c.1453G>T p.D485Y | Missense Mutation (SNP) | VAF 204/335 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99780965; called by muse, mutect2, varscan2
- B3GAT1 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs1167877969, COSV100437855; called by muse, mutect2
- BARD1 | c.1180A>G p.T394A | Missense Mutation (SNP) | VAF 51/372 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as rs587782548, COSV99638523; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTBD3 | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV99655787; called by muse, mutect2, varscan2
- C10orf71 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.208); catalogued as rs775875033, COSV60505914, COSV60515402; called by muse, mutect2, varscan2
- C12orf66 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs759325071, COSV61322402; called by muse, mutect2, varscan2
- CFAP45 | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 119/1469 reads (8%) | catalogued as COSV100928557; called by muse, mutect2
- CHEK2 | c.168C>G p.S56R | Missense Mutation (SNP) | VAF 118/435 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100101502; called by muse, mutect2, varscan2
- CHRNB4 | c.962A>C p.H321P | Missense Mutation (SNP) | VAF 65/234 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99929323; called by muse, mutect2, varscan2
- CRYZL1 | c.796C>T p.Q266* | Nonsense Mutation (SNP) | VAF 132/411 reads (32%) | catalogued as COSV99280917; called by muse, mutect2, varscan2
- CSTF2T | c.586C>A p.H196N | Missense Mutation (SNP) | VAF 94/289 reads (33%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV100484155; called by muse, mutect2, varscan2
- DGKI | c.2943C>T p.H981= | Splice Region (SNP) | VAF 153/561 reads (27%) | catalogued as rs79823365, COSV55934547; called by muse, mutect2, varscan2
- DNAJC13 | c.3452C>G p.A1151G | Missense Mutation (SNP) | VAF 84/297 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as rs754880650, COSV53454303; called by muse, mutect2, varscan2
- ELMOD3 | c.835A>C p.K279Q | Missense Mutation (SNP) | VAF 11/392 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99809387; called by muse, mutect2
- EP300 | c.5591C>G p.T1864S | Missense Mutation (SNP) | VAF 81/326 reads (25%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV99608278; called by muse, mutect2, varscan2
- F5 | c.3779C>T p.P1260L | Missense Mutation (SNP) | VAF 437/1821 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); catalogued as COSV100889062; called by muse, mutect2, varscan2
- FAM135B | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 17/254 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771996168, COSV50523016; called by muse, mutect2
- FASTKD1 | c.1188dup p.A397Cfs*4 | Frame Shift Ins (INS) | VAF 73/309 reads (24%) | catalogued as rs770112643; called by mutect2, pindel, varscan2
- FAT2 | c.11819C>T p.A3940V | Missense Mutation (SNP) | VAF 51/218 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.203); catalogued as rs746102336, COSV99942552; called by muse, mutect2, varscan2
- GBA | c.1305C>A p.N435K | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100516324; called by muse, mutect2, varscan2
- GNA15 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 76/249 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as COSV99505167; called by muse, mutect2, varscan2
- GOT1 | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.063); catalogued as COSV100981710; called by muse, mutect2, varscan2
- HMCN1 | c.6557A>T p.N2186I | Missense Mutation (SNP) | VAF 39/508 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54913004, COSV54917670; called by muse, mutect2
- KMT2C | c.3545C>G p.S1182* | Nonsense Mutation (SNP) | VAF 84/307 reads (27%) | catalogued as COSV100070812; called by muse, mutect2, varscan2
- KRTAP11-1 | c.158T>C p.L53P | Missense Mutation (SNP) | VAF 50/252 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs1283197879, COSV100190600; called by muse, mutect2, varscan2
- LCMT2 | c.1118C>G p.A373G | Missense Mutation (SNP) | VAF 71/217 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV99980042; called by muse, mutect2, varscan2
- MAP3K21 | c.904del p.M302* | Frame Shift Del (DEL) | VAF 78/409 reads (19%) | catalogued as rs1475537784, COSV64043459; called by mutect2, pindel, varscan2
- MARK2 | c.332A>G p.N111S | Missense Mutation (SNP) | VAF 196/758 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100158454; called by muse, mutect2, varscan2
- MED1 | c.3902C>T p.P1301L | Missense Mutation (SNP) | VAF 104/349 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs756858854, COSV100327729; called by muse, mutect2, varscan2
- MUC16 | c.22520C>T p.A7507V | Missense Mutation (SNP) | VAF 111/387 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as COSV101199525; called by muse, mutect2, varscan2
- NCF4 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs371008750; called by muse, mutect2, varscan2
- PACRG | c.484C>T p.R162* | Nonsense Mutation (SNP) | VAF 145/334 reads (43%) | catalogued as rs369094995; called by muse, mutect2, varscan2
- PCDHGB7 | c.2116G>A p.A706T | Missense Mutation (SNP) | VAF 118/350 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0.021); catalogued as rs372316838; called by muse, mutect2, varscan2
- PGBD5 | c.455G>A p.R152H (on ENST00000525115; = p.R221H on NM_001258311.2) | Missense Mutation (SNP) | VAF 70/372 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs773389998, COSV58412512; called by muse, mutect2, varscan2
- PHF3 | c.3111G>T p.M1037I | Missense Mutation (SNP) | VAF 38/248 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.597); catalogued as COSV100013210; called by muse, varscan2
- PLXNB1 | c.1761G>A p.M587I | Missense Mutation (SNP) | VAF 163/356 reads (46%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99602727; called by muse, mutect2, varscan2
- PRX | c.2690G>A p.R897Q | Missense Mutation (SNP) | VAF 107/425 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs752531623, COSV99397522, COSV99397940; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RCAN3 | c.422C>G p.P141R | Missense Mutation (SNP) | VAF 96/173 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100980335; called by muse, mutect2, varscan2
- RREB1 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs747673605, COSV100619293; called by muse, mutect2, varscan2
- SLC6A17 | c.1502G>A p.C501Y | Missense Mutation (SNP) | VAF 121/239 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100521226; called by muse, mutect2, varscan2
- TAS2R4 | c.121A>G p.I41V | Missense Mutation (SNP) | VAF 161/614 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.017); catalogued as COSV99924646; called by muse, mutect2, varscan2
- TRPM1 | c.1817G>T p.S606I | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as COSV99855793; called by muse, mutect2, varscan2
- DAAM1 | c.1363dup p.M455Nfs*7 | Frame Shift Ins (INS) | VAF 86/398 reads (22%) | called by mutect2, pindel, varscan2
- ABCC2 | c.1350A>G p.L450= | Silent (SNP) | VAF 51/309 reads (17%) | catalogued as COSV100966464; called by muse, mutect2, varscan2
- ALPK3 | c.1588C>A p.R530= | Silent (SNP) | VAF 58/179 reads (32%) | catalogued as COSV99360213; called by muse, mutect2, varscan2
- ATF7IP2 | c.105T>C p.V35= | Silent (SNP) | VAF 97/312 reads (31%) | catalogued as rs187860514, COSV100202587; called by muse, mutect2, varscan2
- C11orf87 | c.321C>T p.S107= | Silent (SNP) | VAF 115/451 reads (25%) | catalogued as rs768536867, COSV59357576; called by muse, mutect2, varscan2
- CRISPLD1 | c.732G>C p.G244= | Silent (SNP) | VAF 64/515 reads (12%) | catalogued as COSV100081875; called by muse, mutect2, varscan2
- ENPP2 | c.408G>A p.V136= | Silent (SNP) | VAF 97/317 reads (31%) | catalogued as COSV99308075; called by muse, mutect2, varscan2
- HECTD4 | c.8625C>T p.I2875= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as COSV101107309; called by muse, mutect2, varscan2
- JAK2 | c.1155A>G p.K385= | Silent (SNP) | VAF 73/158 reads (46%) | catalogued as COSV101072524; called by muse, mutect2, varscan2
- NKAPL | c.447C>T p.D149= | Silent (SNP) | VAF 194/728 reads (27%) | catalogued as COSV59198478; called by muse, mutect2, varscan2
- NLGN4Y | c.1203C>T p.N401= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as COSV100196692; called by muse, mutect2, varscan2
- OSBPL6 | c.2259T>C p.N753= | Silent (SNP) | VAF 76/238 reads (32%) | catalogued as rs758712723, COSV99507235; called by muse, mutect2, varscan2
- RP1 | c.324C>T p.H108= | Silent (SNP) | VAF 152/462 reads (33%) | catalogued as rs141074157; called by muse, mutect2, varscan2
- SNX27 | c.807C>T p.Y269= | Silent (SNP) | VAF 49/237 reads (21%) | catalogued as COSV100919016; called by muse, mutect2, varscan2
- SYNDIG1 | c.747C>T p.I249= | Silent (SNP) | VAF 234/595 reads (39%) | catalogued as rs771960685, COSV65239387; called by muse, mutect2, varscan2
- ZNF317 | c.1353C>T p.C451= | Silent (SNP) | VAF 43/171 reads (25%) | catalogued as rs769753252, COSV99927056; called by muse, mutect2, varscan2
- STAG3L4 | n.728A>C | RNA (SNP) | VAF 43/285 reads (15%) | called by muse, mutect2, varscan2
- TRAK1 | c.1963+214T>G | Intron (SNP) | VAF 452/993 reads (46%) | catalogued as COSV100409928; called by muse, varscan2
